Somatic mutation profile of cancer-model specimen HCM-BROD-0676-C71-85R (Adherent Cell Line, passage 6; aliquot HCM-BROD-0676-C71-85R-01D-A85C-36), derived from the recurrence tumor of HCMI case HCM-BROD-0676-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.0 years (22,652 days).
Specimen HCM-BROD-0676-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc08202-e6c5-4ed9-9855-d36e2ec549c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0676-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0676-C71-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda12ffb-2871-4b14-8305-fbe4ca35db6b

The open-access MAF lists 91 somatic variants for this specimen: 72 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 7, Frame Shift Del 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCDH | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 273/605 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs200639270, CM000391, COSV55819438; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.492+1del | Frame Shift Del (DEL) | VAF 97/139 reads (70%) | catalogued as rs1564830522; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB4 | c.2038A>G p.S680G | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs759327146; called by muse, mutect2, varscan2
- ASIC3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 373/1134 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as rs764927092; called by muse, mutect2, varscan2
- B3GNT3 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs769736671, COSV57953699; called by muse, mutect2, varscan2
- CDHR4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 243/513 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1030618164, COSV100323466; called by muse, varscan2
- CHRNA9 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 239/502 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs113015603, COSV100038975; called by muse, mutect2, varscan2
- CLSTN3 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 197/429 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs370059456; called by muse, varscan2
- CNDP1 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 175/335 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs750357285; called by muse, mutect2, varscan2
- CNGA3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as rs772689125; called by muse, varscan2
- CNTNAP2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 134/467 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV62248397; called by muse, varscan2
- DOCK8 | c.221G>C p.S74T | Missense Mutation (SNP) | VAF 196/403 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs563918671; called by muse, mutect2, varscan2
- DOK1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 209/436 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs758234990; called by muse, mutect2, varscan2
- EPHA7 | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 198/419 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs149093618; called by muse, mutect2, varscan2
- GABRA5 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59482675; called by muse, varscan2
- GPR139 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 202/417 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs144787739, COSV58502184; called by muse, varscan2
- GRB7 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 215/392 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772287804, COSV100485619; called by muse, mutect2, varscan2
- GUCY2D | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 248/468 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs1189197351; called by muse, mutect2, varscan2
- IL18RAP | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.273); catalogued as COSV99962134; called by muse, mutect2, varscan2
- ITGAL | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 148/318 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757861462, COSV100776114; called by muse, mutect2, varscan2
- JPH2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 343/707 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65902431; called by muse, varscan2
- KIF17 | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 205/458 reads (45%) | catalogued as rs1389913702; called by muse, varscan2
- KRTAP10-11 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 378/753 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369473800; called by muse, varscan2
- LARP6 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 214/455 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs371576145; called by muse, mutect2, varscan2
- LMOD3 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 196/439 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV70456707; called by muse, varscan2
- MAGEB1 | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100974955; called by muse, varscan2
- MAST2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100787799, COSV63616233; called by muse, varscan2
- MPP4 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 98/233 reads (42%) | catalogued as rs755630027; called by muse, mutect2, varscan2
- MYCBP2 | c.7292G>A p.R2431Q (on ENST00000357337; = p.R2469Q on NM_015057.5) | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs761790230; called by muse, mutect2, varscan2
- NAV2 | c.69del p.I24Sfs*16 | Frame Shift Del (DEL) | VAF 453/1100 reads (41%) | catalogued as rs1226338018; called by mutect2, pindel, varscan2
- OR5M1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 208/420 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868634595, COSV73202072; called by muse, varscan2
- PCDHA3 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 472/920 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.223); catalogued as rs781849256, COSV100793292; called by muse, varscan2
- PCDHGA3 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 462/914 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as rs745349592, COSV53916955, COSV54017901; called by muse, varscan2
- PER1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 262/554 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs760115782, COSV57920449; called by muse, mutect2, varscan2
- PIWIL1 | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 51/732 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1457540291; called by muse, mutect2
- PROK2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 107/224 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs773442177, CM111637; called by muse, varscan2
- PXDNL | c.1799T>C p.I600T | Missense Mutation (SNP) | VAF 134/260 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV62492858; called by muse, varscan2
- SALL4 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 295/609 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370973464, COSV53854735; called by muse, mutect2, varscan2
- SEMA3E | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 199/652 reads (31%) | catalogued as rs1350303800, COSV100319493; called by muse, mutect2, varscan2
- SH2D4B | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 170/170 reads (100%) | catalogued as rs370788593; called by muse, varscan2
- SH3TC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 198/431 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs375791903; called by muse, mutect2, varscan2
- STAG2 | c.1907dup p.Y636* | Nonsense Mutation (INS) | VAF 172/241 reads (71%) | catalogued as COSV54350437; called by mutect2, pindel, varscan2
- TTN | c.63154A>G p.T21052A (on ENST00000591111; = p.T13628A on NM_003319.4) | Missense Mutation (SNP) | VAF 50/372 reads (13%) | PolyPhen probably damaging (0.994); catalogued as COSV104414496; called by muse, varscan2
- ZNF619 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 207/442 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759309766; called by muse, mutect2, varscan2
- ZNF700 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 156/329 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs370568041; called by muse, mutect2, varscan2
- AGTR1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 15/551 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.065); called by muse, mutect2
- AHCYL1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- C2orf16 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 178/349 reads (51%) | SIFT tolerated (0.91); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CALML6 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 159/360 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CDS1 | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CFAP58 | c.1033del p.A345Qfs*10 | Frame Shift Del (DEL) | VAF 213/302 reads (71%) | called by mutect2, pindel, varscan2
- CSNK1D | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DHTKD1 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT tolerated (0.73); PolyPhen benign (0.147); called by muse, varscan2
- DIAPH3 | c.2444A>T p.N815I (on ENST00000400324 / NM_001042517.2; = p.N552I on NM_030932.3) | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ENPEP | c.2629T>G p.Y877D | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.8285C>A p.T2762K | Missense Mutation (SNP) | VAF 176/343 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- GSK3A | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 164/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INCENP | c.2098C>T p.Q700* (on ENST00000394818 / NM_001040694.2; = p.Q696* on NM_020238.3) | Nonsense Mutation (SNP) | VAF 374/834 reads (45%) | called by muse, varscan2
- INTS3 | c.3044G>T p.S1015I | Missense Mutation (SNP) | VAF 235/446 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MFSD1 | c.1121G>A p.W374* | Nonsense Mutation (SNP) | VAF 155/317 reads (49%) | called by muse, mutect2, varscan2
- MYO5B | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by mutect2, varscan2
- NLRP6 | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 287/575 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR4A1 | c.1003del p.E335Kfs*8 | Frame Shift Del (DEL) | VAF 187/471 reads (40%) | called by mutect2, pindel, varscan2
- NT5E | c.1717T>C p.Y573H | Missense Mutation (SNP) | VAF 143/269 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIEZO2 | c.3509G>A p.C1170Y | Missense Mutation (SNP) | VAF 232/474 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- REG3A | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 203/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPING1 | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 37/769 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- SIRPB1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 175/411 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC25A1 | c.274T>A p.Y92N | Missense Mutation (SNP) | VAF 208/210 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, varscan2
- TLR3 | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 213/496 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- TMEM106A | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 130/446 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, varscan2
- TMX2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 228/464 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, varscan2
- ATP7A | c.1692T>A p.G564= | Silent (SNP) | VAF 153/153 reads (100%) | called by muse, mutect2, varscan2
- CCDC8 | c.636T>C p.G212= | Silent (SNP) | VAF 372/787 reads (47%) | called by muse, mutect2, varscan2
- CENPJ | c.777G>A p.A259= | Silent (SNP) | VAF 146/280 reads (52%) | catalogued as rs748696673, COSV101121539; called by muse, varscan2
- CHRNG | c.1215G>A p.R405= | Silent (SNP) | VAF 192/403 reads (48%) | catalogued as COSV67315642; called by muse, varscan2
- CNGA3 | c.354G>A p.Q118= | Silent (SNP) | VAF 146/347 reads (42%) | called by muse, varscan2
- COL15A1 | c.1605G>A p.P535= | Silent (SNP) | VAF 290/615 reads (47%) | catalogued as rs547671721, COSV66643026; called by muse, mutect2, varscan2
- CSMD2 | c.1452G>A p.P484= | Silent (SNP) | VAF 113/257 reads (44%) | catalogued as rs201089989; called by muse, mutect2, varscan2
- ECPAS | c.2592T>C p.V864= | Silent (SNP) | VAF 130/297 reads (44%) | called by muse, mutect2, varscan2
- FAT3 | c.8286A>G p.T2762= | Silent (SNP) | VAF 176/345 reads (51%) | called by muse, varscan2
- GP1BA | c.1764G>T p.V588= | Silent (SNP) | VAF 279/595 reads (47%) | catalogued as rs1269272959; called by muse, mutect2, varscan2
- KIF26A | c.4560C>A p.A1520= | Silent (SNP) | VAF 456/916 reads (50%) | called by muse, mutect2, varscan2
- KRT76 | c.1659C>T p.G553= | Silent (SNP) | VAF 425/842 reads (50%) | catalogued as rs778936647; called by muse, varscan2
- MAST4 | c.498C>T p.S166= | Silent (SNP) | VAF 151/302 reads (50%) | called by muse, varscan2
- MCF2 | c.1887C>A p.L629= | Silent (SNP) | VAF 119/119 reads (100%) | catalogued as COSV100644781; called by muse, mutect2, varscan2
- PLEKHH1 | c.2080C>T p.L694= | Silent (SNP) | VAF 198/410 reads (48%) | called by muse, mutect2
- SFT2D3 | c.84C>T p.A28= | Silent (SNP) | VAF 390/751 reads (52%) | called by muse, varscan2
- SOD1 | c.462A>G p.Q154= | Silent (SNP) | VAF 119/225 reads (53%) | catalogued as rs1465781849; called by muse, varscan2
- TMEM106A | c.24G>T p.L8= | Silent (SNP) | VAF 128/443 reads (29%) | called by muse, varscan2
- MXRA8 | chr1:1361257 G>A | 5'Flank (SNP) | VAF 194/377 reads (51%) | catalogued as rs1052450459; called by muse, mutect2, varscan2
